Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5706, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5706-01A (Primary Tumor).

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Left renal cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Left radical nephrectomy.

FINAL DIAGNOSIS:**PART 1, KIDNEY, LEFT, NEPHRECTOMY**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE, FUHRMAN'S NUCLEAR GRADE IS (II OF IV)
- B. RENAL CELL CARCINOMA GROWS IN ACINAR SOLID PATTERN OF GROWTH
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 8.5 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE (SEE COMMENT)
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE
- I. THE ADRENAL GLAND IS UNREMARKABLE
- J. THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED):0/0
- K. TNM STAGE: pT2 NXMX.

PART 2, PERITONIUM, EXCISION-

FIBROADIPOSE TISSUE, NEGATIVE FOR CARCINOMA

COMMENT:

There is an area of tumor focally in the perinephric adipose tissue in slide 1F. This most likely represents an artifact occurring during sectioning and processing. Therefore, our overall interpretation is that the renal cell carcinoma in this case is organ-confined and the pathologic stage is pT2.

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

SYNOPTIC - PRIMARY Kidney/Renal Pelvis/Ureter TUMORS

- | | | |
|--|-------------|---|
| A. Side: 2 | 1. Right | 2. Left |
| B. Location: 1 | | |
| 1. Kidney (parenchyma - cortex/medulla) | | 3. Ureter |
| 2. Kidney (pelvis) | | 4. Kidney and ureter |
| C. Procedure: 3 | | |
| 1. Partial nephrectomy | | 4. Ureterectomy |
| 2. Simple nephrectomy | | 5. Other |
| 3. Radical nephrectomy | | |
| D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): | 8.5 cm | |
| E. Type of malignant neoplasm: 1 | | |
| 1. Renal cell carcinoma, clear cell type (includes non-papillary granular cell RCC) | | 11. Urothelial carcinoma, small cell/neuroendocrine carcinoma |
| 2. Renal cell carcinoma, chromophil cell type (papillary RCC, no clear cell component) | | 12. Urothelial carcinoma, mixed |
| 3. Renal cell carcinoma, chromophobe cell type | | 13. Juxtaglomerular cell tumor |
| 4. Renal cell carcinoma, oncocytic | | 14. Wilms' tumor |
| 5. Renal cell carcinoma, sarcomatoid | | 15. Rhabdoid tumor |
| 6. Collecting duct carcinoma | | 16. Clear cell sarcoma |
| 7. Urothelial carcinoma, TCCa (non-invasive) | | 17. Congenital mesoblastic nephroma |
| 8. Urothelial carcinoma, TCCa (invasive ± in-situ) | | 18. Sarcoma (non-clear cell) |
| 9. Urothelial carcinoma, squamous carcinoma | | 19. Lymphoma/leukemia |
| 10. Urothelial carcinoma, adenocarcinoma | | 20. Other |
| F. Histologic grade 2 | | |
| F1. Fuhrman grade (for RCC, grades 1-4): 2 | | |
| F2. Ash grade (grade 1-4): # | | |
| F3. WHO grade (grade 1-3): # (for TCCa) | | |
| F4. 1998 WHO/ISUP Classification: # | | |
| 1. LMP | 2. LG | 3. HG |
| F5. Other malignant neoplasms (grades 1-3): # | | |
| G. Non-neoplastic and other conditions: # / # / # / # | | |
| 1. Glomerulopathy | | |
| 2. Interstitial nephritis | | |
| 3. Pyelonephritis | | |
| 4. Nephrolithiasis | | |
| 5. Papillary necrosis | | |
| 6. Chronic parenchymal disease | | |
| 7. Other | | |
| H. Margins of resection: 2 | 1. Positive | 2. Negative |
| I. Mitotic activity: 1 per 10 high power fields | | |
| J. Angiolymphatic invasion | | |
| J1. Macroscopic (e.g., renal vein thrombus): 2 | 1. Positive | 2. Negative |
| J2. Microscopic: 2 | 1. Positive | 2. Negative |
| K. Number of positive lymph nodes: 0 | | |
| L. Total number of lymph nodes examined: 0 | | |
| M. Extracapsular spread of lymph node metastases: N/A | | |
| 1. Yes | 2. No | |
| N. Adrenal gland: | | |
| N1. Present 1 | 1. Yes | 2. No |
| N2. Involvement by renal neoplasm: 2 | 1. Yes | 2. No |
| N3. Other adrenal pathology, #2 | 1. Yes | 2. No |
| O. TNM stage: T 2 N X M X | | |

Source: NCI Genomic Data Commons file 6a8cfbc9-ad9d-471e-9e3a-a6f7abbd405c (TCGA-B0-5706.BCD56ADD-DE3B-4E24-94BC-95648D30AD32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).